Somatic mutation profile of tumor specimen TCGA-UD-AAC5-01A (aliquot TCGA-UD-AAC5-01A-11D-A39R-32) from TCGA case TCGA-UD-AAC5, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.6 years (24,314 days).
Specimen TCGA-UD-AAC5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb06f23c-6cda-40f1-9c06-30feb46fd576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UD-AAC5-10A (Blood Derived Normal), aliquot TCGA-UD-AAC5-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02a1e65a-3147-4747-9037-e7b1dc2de66d

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 14, Silent 9, Splice Site 2, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- MKS1 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs373471917, COSV58304562; called by muse, mutect2, varscan2
- NEK2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177477304, COSV65357752; called by muse, mutect2, varscan2
- NF2 | c.1446+1G>C p.X482_splice | Splice Site (SNP) | VAF 19/39 reads (49%) | catalogued as HS040015, COSV58521472, COSV58521734, COSV58525323; called by muse, mutect2, varscan2
- OGDHL | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.186); catalogued as COSV65103162; called by muse, mutect2, varscan2
- RMDN1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/38 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs537592205; called by muse, mutect2, varscan2
- ANKLE1 | c.1078C>G p.P360A (on ENST00000394458; = p.P306A on NM_152363.6) | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AQP11 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARL4C | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCND3 | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FBXL7 | c.967T>A p.C323S | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GAL3ST3 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ITCH | c.1559C>G p.P520R (on ENST00000262650 / NM_001257137.3; = p.P479R on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHGC4 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHRF1 | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP5KL1 | c.205G>T p.V69F | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SFTPB | c.529del p.V177Sfs*38 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- SLC29A4 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP15 | c.3489C>T p.L1163= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as rs768674975, COSV52273125; called by muse, mutect2, varscan2
- ITGB3 | c.2070C>A p.V690= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- MXRA5 | c.1425C>T p.S475= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as COSV99476730; called by muse, mutect2, varscan2
- NPAP1 | c.888G>A p.L296= | Silent (SNP) | VAF 25/286 reads (9%) | catalogued as rs1218280651, COSV61509204; called by muse, mutect2
- NUP155 | c.3642T>G p.P1214= (on ENST00000231498 / NM_153485.3; = p.P1155= on NM_004298.4) | Silent (SNP) | VAF 54/94 reads (57%) | called by muse, mutect2, varscan2
- PASK | c.2892C>G p.P964= | Silent (SNP) | VAF 29/51 reads (57%) | called by muse, mutect2, varscan2
- PDE3A | c.2265C>T p.I755= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- UTP23 | c.453T>C p.S151= | Silent (SNP) | VAF 43/69 reads (62%) | called by muse, mutect2, varscan2
- ZNF493 | c.1785C>T p.N595= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
